Surgical pathology report (de-identified scan), TCGA case TCGA-DA-A1I1, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site Yale, specimen TCGA-DA-A1I1-06A (Metastatic).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

ICD-0-3

Melanoma, NOS 8720/3

Site: Skin, NOS C44.9 3/12/11 hr

Clinical History and Impression:

Cholelithiasis

year old male with RUQ pain; cholelithiasis. PET 6/08: multiple lesions; right pelvic x 1; anterior abdominal wall x 1; pelvic nodules present for laparoscopic cholecystectomy and resection of abdominal wall mass.

Specimen(s) Received:

1: GALLBLADDER

2: RIGHT ABDOMINAL WALL NODULE

FINAL DIAGNOSIS

1) GALLBLADDER, CHOLECYSTECTOMY:

- CHOLELITHIASIS
- OTHERWISE UNREMARKABLE GALLBLADDER

2) RIGHT ABDOMINAL WALL NODULE, EXCISION:

- CIRCUMSCRIBED NODULE OF METASTATIC MALIGNANT MELANOMA
- MELANOMA CELLS ARE S100 AND MELAN-A POSITIVE

Pathologist:

M.D.

* Report Electronically Signed Out *

This electronic signature indicates that the pathologist has personally reviewed the available gross and/or microscopic material and has based the diagnosis on that evaluation.

Gross Description:

1) Received fresh, labeled with the patient's name and "gallbladder" is a product of a cholecystectomy consisting of 8.5 x 4.2 x 1.6 cm gallbladder. The serosal surface is smooth and shiny with congested blood vessels. The liver aspect of the gallbladder is identified. The cystic duct margin is inked black. There are few yellow bosselated gallstones ranging in size from 0.1 x 0.1 x 0.15 cm to 0.2 x 0.3 x 0.3 cm. The gallbladder mucosa is smooth and green. No gross lesions are identified. The gallbladder wall thickness ranges from 0.2 cm to 0.3 cm. Representative sections are submitted in one cassette with the cystic duct margin inked black.

2) Received fresh, labeled with the patient's name and "right abdominal wall nodule" is a 2.2 x 2.8 x 1.8 cm tan-white nodule with attached tan-pink soft tissue. The nodule appears to be transected. A gross photograph is taken. The soft

[page 2 of 2]
SURGICAL PATHOLOGY REPORT

tissue aspect of the mass is inked black. The specimen is serially sectioned to reveal a uniform tan cut surface. Representative sections are submitted in two cassettes.

Summary of Stains Performed and Reviewed

Count
1
1

Melan-A *
S-100 Protein *

*The immunohistochemical profile may include the use of Analyte Specific Reagents, or Research Agents, whose performance characteristics have not been established by the supplier. The histochemical tests were developed and their performance characteristics were determined by the ~~Pathology~~ Pathology Laboratory. It has not been cleared or approved by the U.S. Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary for this test. These tests are used for clinical purposes and should not be regarded as investigational or for research. This laboratory is regulated under the Clinical Laboratory Improvements Amendments of 1988 (CLIA) as qualified to perform high complexity clinical testing. External and internal controls stained appropriately.

Summary of Tissue Submitted for Microscopic Examination

Block Detail

	# Blocks	Designation	#	Description
Part 1) GALLBLADDER	1	GB	(1)	Gallbladder
Part 2) RIGHT ABDOMINAL WALL NODULE	2	M	(2)	Mass
Total:	3			

END OF REPORT

Source: NCI Genomic Data Commons file 708477ad-3eff-4304-b96e-5130f93a3488 (TCGA-DA-A1I1.3B67C83B-2998-4A34-A1FE-96D6EB776636.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).